Somatic mutation profile of tumor specimen MP2PRT-PAVPPB-TMP1-A (aliquot MP2PRT-PAVPPB-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVPPB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,328 days).
Specimen MP2PRT-PAVPPB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe127d85-899c-407f-b2e5-6127a9214f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPPB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPPB-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0737176c-5ec9-44ac-8113-8732a9cea99c

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 2, Silent 2, Intron 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.066); catalogued as rs1297553338, COSV55612224; called by muse, mutect2
- FGD5 | c.2686A>G p.I896V | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as rs757337808; called by muse, mutect2, varscan2
- GRM8 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs139289550; ClinVar: uncertain significance; called by muse, mutect2
- PNLDC1 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs201062377, COSV104368595; called by muse, mutect2, varscan2
- SNX25 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs371436770; called by muse, mutect2, varscan2
- EPHB4 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 191/409 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, varscan2
- ETV6 | c.127_144delinsTCTAAA p.M43_I48delinsSK | In Frame Del (DEL) | VAF 14/133 reads (11%) | called by pindel, varscan2*
- ETV6 | c.1293dup p.D432Rfs*13 | Frame Shift Ins (INS) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- KMT2D | c.15270_15271insT p.K5091* | Frame Shift Ins (INS) | VAF 171/407 reads (42%) | called by mutect2, pindel*, varscan2
- LRP1B | c.11058C>A p.C3686* | Nonsense Mutation (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- UBE2D3 | c.304+1_304+4delinsCCCTAAGG p.X102_splice | Splice Site (INS) | VAF 82/174 reads (47%) | called by pindel, varscan2*
- ZDHHC15 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NBEA | c.4161C>T p.S1387= | Silent (SNP) | VAF 22/376 reads (6%) | catalogued as COSV59758959; called by muse, mutect2
- PTPRA | c.1248C>T p.T416= | Silent (SNP) | VAF 133/313 reads (42%) | catalogued as rs1318442397, COSV53777838; called by muse, mutect2, varscan2
- DNAH14 | c.1825+635G>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
